Gene-level copy-number profile of tumor specimen ALCH-B3IH-TTP1-A from ALCHEMIST case ALCH-B3IH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,215 days).
Specimen ALCH-B3IH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86afdcc3-d46d-463e-9ed3-537d262a1640.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3IH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/81bc0471-57af-432f-8fb6-c9333067e574

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,434; copy number 2: 55,460; copy number 3: 436; copy number 4: 665; copy number 5: 161; copy number 6: 148; copy number 7: 6; copy number 8: 9; copy number 9: 72; copy number 10: 1; copy number 14: 1; copy number 15: 1; copy number 21: 5; copy number 39: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,555,214–129,632,492, 3 genes: PLXND1, RN7SL752P, AC023162.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 405 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–10,777,062, 231 genes, copy number 5–8 (broad region; genes not listed).
- chr20:56,667,430–57,409,333, 21 genes, copy number 6: RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38.
- chr20:61,252,261–64,327,972, 142 genes, copy number 5–9 (broad region; genes not listed).
- chr21:43,414,483–43,479,534, 4 genes, copy number 10–39: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5–6 (within-gene range 2–6): PWP2, GATD3A.
- chr21:44,217,014–44,262,216, 5 genes, copy number 21: ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 1,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
